Surgical pathology report (de-identified scan), TCGA case TCGA-RQ-A6JB, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RQ-A6JB-01A (Primary Tumor).

Diagnosis:

Subgaleal Mass

-Large Cell Lymphoma, B-Cell Type of probable follicular center cell origin.

ICD-O-3
Diffuse Large B Cell
Lymphoma 9680/3
Site: Bone of skull, face
and associated parts C41.0
JW 6/28/13

Discussion:

The neoplastic cells are immunoreactive for CD45 and CD20. Scattered CD3 positive T-cells are present as well as scattered CD68 positive monocytes/macrophage lineage cells. The tumor cells are diffusely immunoreactive for vimentin. They are negative for cytokeratin, CD 99, desmin, synaptophysin, S-100 and CD34. Overall, the findings confirm a diagnosis of a B-cell lymphoma.

Microscopic Description:

Sections demonstrate sheets of large, non-cohesive cells. Whereas the nuclei are enlarged, there is only modest cytoplasm. The nuclei range from open to hyperchromatic and rounded to angulated to cleaved and lobulated. Scattered mitotic figures are seen. There are no specifics differentiating features.

Hist/AA Discrepancy		/

Source: NCI Genomic Data Commons file 8e33f6a5-dbe4-4c1d-9a48-06fe6ac1f9fe (TCGA-RQ-A6JB.0250A7AA-A53D-4DCB-BF74-04FABD979B25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).